Somatic mutation profile of tumor specimen TCGA-06-0152-01A (aliquot TCGA-06-0152-01A-02W-0323-08) from TCGA case TCGA-06-0152, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 68.0 years (24,844 days).
Specimen TCGA-06-0152-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 30adffcb-5dfc-4e2c-8032-cb2ef4a583cb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-06-0152-10A (Blood Derived Normal), aliquot TCGA-06-0152-10A-01D-1492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/1c129614-48ae-4bb6-904e-0ac64b39ea4a

The open-access MAF lists 67 somatic variants for this specimen: 55 protein-altering or splice-affecting, 12 silent.
By variant classification: Missense Mutation 30, Frame Shift Ins 19, Silent 12, Nonsense Mutation 3, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MSH6 | c.3261dup p.F1088Lfs*5 | Frame Shift Ins (INS) | VAF 32/213 reads (15%) | hotspot (GDC flag); catalogued as rs267608078; ClinVar: pathogenic; called by mutect2, varscan2
- AIDA | c.291C>G p.I97M | Missense Mutation (SNP) | VAF 75/107 reads (70%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.916); catalogued as COSV60663434; called by muse, varscan2
- ALPK3 | c.2234C>A p.A745E | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV51931683; called by muse, mutect2, varscan2
- ATP1A4 | c.2162C>A p.T721K | Missense Mutation (SNP) | VAF 86/682 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63625401, COSV63625971; called by muse, varscan2
- CCDC33 | c.308C>T p.A103V | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as COSV58349692; called by muse, mutect2, varscan2
- CD8A | c.695C>T p.A232V | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.014); catalogued as rs1427820128, COSV52156884; called by muse, mutect2, varscan2
- CDH24 | c.714dup p.L239Afs*67 | Frame Shift Ins (INS) | VAF 10/65 reads (15%) | catalogued as rs765496989; called by mutect2, varscan2
- CITED1 | c.521C>T p.P174L | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV55744420; called by muse, mutect2
- CNMD | c.71dup p.A25Gfs*78 | Frame Shift Ins (INS) | VAF 4/20 reads (20%) | catalogued as rs768157613; called by pindel, varscan2
- DIMT1 | c.897del p.R300Dfs*29 | Frame Shift Del (DEL) | VAF 85/282 reads (30%) | catalogued as COSV52235192; called by mutect2, pindel, varscan2
- DOCK7 | c.3932C>G p.S1311* (on ENST00000635253 / NM_001367561.1; = p.S1280* on NM_033407.3) | Nonsense Mutation (SNP) | VAF 39/232 reads (17%) | catalogued as COSV52000635; called by muse, mutect2, varscan2
- ENO3 | c.1240G>A p.E414K | Missense Mutation (SNP) | VAF 39/96 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); catalogued as rs773760593, COSV52776709; called by muse, mutect2, varscan2
- FILIP1 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 68/155 reads (44%) | catalogued as COSV52725951, COSV52735038; called by muse, mutect2, varscan2
- GBP7 | c.1293dup p.H432Afs*12 | Frame Shift Ins (INS) | VAF 11/99 reads (11%) | catalogued as rs754177800; called by mutect2, varscan2
- GCNT4 | c.880dup p.H294Pfs*2 | Frame Shift Ins (INS) | VAF 23/188 reads (12%) | catalogued as rs768450027; called by mutect2, varscan2
- GLYR1 | c.1140dup p.R381Afs*15 | Frame Shift Ins (INS) | VAF 28/120 reads (23%) | catalogued as rs749150409; called by mutect2, varscan2
- GRM4 | c.1514G>A p.R505Q | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs561013910, COSV65211913; called by muse, mutect2
- IGDCC4 | c.2613dup p.T872Hfs*22 | Frame Shift Ins (INS) | VAF 12/60 reads (20%) | catalogued as rs761621429; called by mutect2, varscan2
- JCAD | c.3670C>G p.P1224A | Missense Mutation (SNP) | VAF 88/135 reads (65%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.747); catalogued as COSV64758741; called by muse, mutect2, varscan2
- KBTBD6 | c.1326dup p.R443Afs*8 | Frame Shift Ins (INS) | VAF 22/182 reads (12%) | catalogued as rs774820321; called by mutect2, varscan2
- KEL | c.560C>A p.S187Y | Missense Mutation (SNP) | VAF 79/267 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.355); catalogued as COSV62334102, COSV62336854; called by muse, mutect2, varscan2
- LRBA | c.2729G>A p.R910H | Missense Mutation (SNP) | VAF 51/94 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1199894762, COSV63952275, COSV63963465; called by muse, mutect2, varscan2
- LRP1 | c.12575dup p.D4193Rfs*9 | Frame Shift Ins (INS) | VAF 17/80 reads (21%) | catalogued as rs757410385; called by mutect2, varscan2
- MAPRE3 | c.543dup p.C182Lfs*16 | Frame Shift Ins (INS) | VAF 50/207 reads (24%) | catalogued as rs777328830; called by mutect2, varscan2
- NELL1 | c.931C>T p.P311S | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.658); catalogued as rs150066751; called by muse, mutect2, varscan2
- NRXN2 | c.808dup p.A270Gfs*27 | Frame Shift Ins (INS) | VAF 54/250 reads (22%) | catalogued as rs754860965; called by mutect2, varscan2
- PACS1 | c.1060G>A p.V354M | Missense Mutation (SNP) | VAF 113/278 reads (41%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.641); catalogued as COSV57697095; called by muse, mutect2, varscan2
- PEX11A | c.668G>A p.G223E | Missense Mutation (SNP) | VAF 10/33 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55583164; called by muse, mutect2, varscan2
- PGM5 | c.1124G>A p.R375H | Missense Mutation (SNP) | VAF 279/705 reads (40%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.938); catalogued as rs141668530; called by muse, mutect2, varscan2
- PIK3C2B | c.859dup p.R287Pfs*38 | Frame Shift Ins (INS) | VAF 20/145 reads (14%) | catalogued as rs749506841; called by mutect2, varscan2
- PMEPA1 | c.624dup p.S209Qfs*3 | Frame Shift Ins (INS) | VAF 14/101 reads (14%) | catalogued as rs751873496; called by mutect2, varscan2
- PREX1 | c.4810C>T p.R1604W | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1447178153, COSV64249860; called by muse, mutect2, varscan2
- PRMT8 | c.251G>T p.G84V | Missense Mutation (SNP) | VAF 15/22 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.318); catalogued as COSV54212860; called by muse, mutect2, varscan2
- PRPF19 | c.859A>C p.T287P | Missense Mutation (SNP) | VAF 14/126 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs201780573; called by muse, mutect2
- PRRC2A | c.6057dup p.S2020Qfs*25 | Frame Shift Ins (INS) | VAF 5/36 reads (14%) | catalogued as rs774053422; called by mutect2, pindel, varscan2
- PSG7 | c.1243G>T p.D415Y | Missense Mutation (SNP) | VAF 115/341 reads (34%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.601); catalogued as rs773962473, COSV68444724; called by muse, mutect2, varscan2
- RALGAPB | c.1142dup p.H382Tfs*2 | Frame Shift Ins (INS) | VAF 54/413 reads (13%) | catalogued as rs756557178; called by mutect2, varscan2
- RELN | c.1093G>A p.D365N | Missense Mutation (SNP) | VAF 72/420 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.985); catalogued as rs1187393292, COSV58993482; called by muse, mutect2, varscan2
- SEC63 | c.981A>C p.K327N | Missense Mutation (SNP) | VAF 94/228 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.88); catalogued as COSV64599121; called by muse, mutect2, varscan2
- SERPINB5 | c.383C>T p.T128M | Missense Mutation (SNP) | VAF 29/102 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs145559318, COSV66975210; called by muse, mutect2
- SIPA1L1 | c.997C>T p.H333Y | Missense Mutation (SNP) | VAF 122/290 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as COSV62169293; called by muse, mutect2, varscan2
- SLC9A2 | c.2243dup p.T749Nfs*22 | Frame Shift Ins (INS) | VAF 13/97 reads (13%) | catalogued as rs748701652; called by mutect2, varscan2
- SLC9C2 | c.1744T>G p.C582G | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV62944703; called by muse, mutect2, varscan2
- SLITRK6 | c.118A>C p.K40Q | Missense Mutation (SNP) | VAF 113/210 reads (54%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV68389763; called by muse, mutect2, varscan2
- SSTR4 | c.832G>T p.V278L | Missense Mutation (SNP) | VAF 32/98 reads (33%) | SIFT tolerated (0.74); PolyPhen benign (0.048); catalogued as COSV54797581; called by muse, mutect2
- TFE3 | c.1445dup p.P483Tfs*138 | Frame Shift Ins (INS) | VAF 26/106 reads (25%) | catalogued as rs782753958; called by mutect2, varscan2
- TMC4 | c.917A>C p.D306A (on ENST00000617472 / NM_001145303.3; = p.D300A on NM_144686.4) | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated (0.68); PolyPhen benign (0.012); catalogued as COSV56598829; called by muse, mutect2, varscan2
- TRIM55 | c.817G>T p.E273* | Nonsense Mutation (SNP) | VAF 123/220 reads (56%) | catalogued as COSV52544913; called by muse, mutect2, varscan2
- TYRO3 | c.998G>A p.R333H | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs1338476882, COSV55482078; called by muse, mutect2, varscan2
- ULK4 | c.971A>C p.K324T | Missense Mutation (SNP) | VAF 37/149 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV57203968; called by muse, mutect2, varscan2
- ALPK3 | c.4745A>T p.D1582V | Missense Mutation (SNP) | VAF 12/292 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2
- DNAH2 | c.2827_2829del p.S943del | In Frame Del (DEL) | VAF 20/126 reads (16%) | called by pindel, varscan2
- HMCN1 | c.6557dup p.N2186Kfs*16 | Frame Shift Ins (INS) | VAF 116/194 reads (60%) | called by mutect2, varscan2
- SCNN1G | c.1875dup p.K626Qfs*23 | Frame Shift Ins (INS) | VAF 10/98 reads (10%) | called by mutect2, pindel
- ZNF45 | c.1879del p.L627Ffs*67 | Frame Shift Del (DEL) | VAF 53/343 reads (15%) | called by mutect2, pindel, varscan2
- ALOX12B | c.381C>T p.P127= | Silent (SNP) | VAF 24/69 reads (35%) | catalogued as rs1350613581, COSV100046498, COSV59872008; called by muse, mutect2, varscan2
- DNAJC16 | c.1335A>C p.S445= | Silent (SNP) | VAF 238/398 reads (60%) | catalogued as COSV65448298; called by muse, mutect2, varscan2
- FAM181A | c.243C>T p.S81= | Silent (SNP) | VAF 12/33 reads (36%) | catalogued as rs369127722; called by muse, mutect2, varscan2
- FOXJ1 | c.354G>T p.P118= | Silent (SNP) | VAF 31/75 reads (41%) | catalogued as rs1157058439, COSV53942956; called by muse, mutect2, varscan2
- GAREM1 | c.357C>T p.R119= | Silent (SNP) | VAF 201/530 reads (38%) | catalogued as rs775839313, COSV52507354; called by muse, mutect2, varscan2
- NLRP9 | c.807C>T p.S269= | Silent (SNP) | VAF 100/317 reads (32%) | catalogued as rs780877323, COSV60461356; called by muse, mutect2, varscan2
- OPN5 | c.657C>T p.Y219= | Silent (SNP) | VAF 207/603 reads (34%) | catalogued as rs375529102, COSV55245422; called by muse, mutect2, varscan2
- OR2W3 | c.490C>T p.L164= | Silent (SNP) | VAF 15/232 reads (6%) | catalogued as rs1476202139, COSV99075141; called by muse, mutect2
- PLCB1 | c.231C>T p.H77= | Silent (SNP) | VAF 69/309 reads (22%) | catalogued as rs773937907, COSV62040242; ClinVar: likely benign; called by muse, mutect2, varscan2
- SERPINA11 | c.609G>A p.T203= | Silent (SNP) | VAF 45/102 reads (44%) | catalogued as rs757990411, COSV58241455; called by muse, mutect2, varscan2
- THBS1 | c.1950C>T p.C650= | Silent (SNP) | VAF 17/166 reads (10%) | called by muse, mutect2, varscan2
- TMEM132D | c.1311C>T p.I437= | Silent (SNP) | VAF 244/557 reads (44%) | catalogued as COSV70599498; called by muse, mutect2, varscan2
